Surgical pathology report (de-identified scan), TCGA case TCGA-76-6660, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Thomas Jefferson University, specimen TCGA-76-6660-01A (Primary Tumor).

[page 1 of 2]
[REDACTED]
Patient: [REDACTED]

SURGICAL PATHOLOGY REPORT

[REDACTED] TCGA-76-6660

FINAL DIAGNOSIS:

1. Left parietal BRAIN mass (EXCISION): GLIOBLASTOMA, GRADE iv of iv (who SCALE), SEE MICROSCOPIC DESCRIPTION, SEE NOTE
2. Left parietal BRAIN mass (EXCISION): GLIOBLASTOMA, GRADE iv of iv (who SCALE), SEE MICROSCOPIC DESCRIPTION, SEE NOTE

Comment:

[REDACTED] reviewed selected slides and concurs with the presence of malignancy in this material.

[REDACTED]
Report Electronically Signed on [REDACTED]

This diagnostic report has been personally interpreted by the signatory of record.

Microscopic Description:

The tumor consists of a moderately pleomorphic proliferation of astrocytes. There are numerous mitoses and foci of microvascular proliferation. There is both pseudo-palisading and non-pseudo-palisading necrosis. The findings are diagnostic of a glioblastoma, grade IV of IV (WHO scale).

Frozen Section Diagnosis:

1. Left parietal mass: Glioblastoma. [REDACTED]

Clinical History and Diagnosis:

Left parietal mass

Source of Specimen:

- 1: Left parietal mass
- 2: Left parietal mass
- [REDACTED]

[page 2 of 2]
[REDACTED]

Gross Description:

[REDACTED]

1. Left parietal mass: Received fresh for frozen labeled with the patient's name and #1 left parietal mass is in aggregate of tan-red to tan-white soft tissue measuring 1.5 x 0.7 x 0.3 cm. Touch preps are clear. Approximately 50% of the specimen is amended for frozen section, the remainder is entirely submitted in one additional cassette.
2. Left parietal mass: Received in formalin labeled with the patient's name and #2 left parietal Mass are multiple fragments of tan-white to tan-pink soft tissue measuring 1.4 x 0.5 x 0.3 cm in aggregate dimension. The specimen is entirely submitted in one cassette.

Histology Laboratory
H&E

Immunohistochemistry Notes

1. Quantification of immunohistochemistry assay for ER and PR studies is by the method of Battiafora et.al. Applied Immunohistochemistry, [REDACTED]
2. Hercept Test (DakoCytomation) Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

EGFR pharmDx Clone 2-18C9 Formalin fixed, paraffin embedded. Interpretation follows the manufacturer's recommendation.

Documented by [REDACTED]
[REDACTED]

3. Analyte Specific Reagent (ASCR) Disclaimer. The use of one or more reagents in the above tests is regulated as an analyte specific reagent (ASR).

These tests were developed and their performance characteristics determined by the [REDACTED]
[REDACTED]

They have not been cleared by the US Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary.

[REDACTED]

Source: NCI Genomic Data Commons file 3f0d1ef2-2c75-4d66-87a8-92bb7d715ce7 (TCGA-76-6660.230F31A8-F9B9-46A9-B7D3-D09A4FAD5EE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).